HCMI case HCM-BROD-0116-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1f080fcb-15c8-452a-a083-05ed83098a52

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1961; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 56.7 years (20,721 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T4a; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior treatment: Yes.
   Pathology details: Additional pathology findings: Intestinal metaplasia.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 101 days.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.
   Recorded as not given: neoadjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 154.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Intestinal Metaplasia.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0116-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0116-C16-01A-01-S1-HE: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0116-C16-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0116-C16-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0116-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
